Somatic mutation profile of tumor specimen C3N-02930-01 (aliquot CPT0184810036) from CPTAC case C3N-02930, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.9 years (22,240 days).
Specimen C3N-02930-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb9a05cf-ea8f-4e87-a0c3-53ac612db63b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02930-31 (Blood Derived Normal), aliquot CPT0184870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c3112c4-6a8d-4c81-8212-ed283c7911ba

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, RNA 4, Frame Shift Ins 2, Nonsense Mutation 2, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/246 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.42); catalogued as rs566212629; called by muse, mutect2, varscan2
- ATP6V1G2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 22/309 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV58215138; called by muse, mutect2
- CAPN12 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 23/417 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1312176438; called by muse, mutect2
- GRM8 | c.2288G>A p.C763Y | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237114599; called by muse, mutect2
- KRT1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1375564720, COSV52865403; called by muse, mutect2, varscan2
- NUP205 | c.3739G>T p.A1247S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); catalogued as COSV53658653; called by muse, mutect2, varscan2
- OGDHL | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs772306801, COSV65101628; called by muse, mutect2
- PCDHB15 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 58/858 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50859859; called by muse, mutect2
- SNTB1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs753694409, COSV67324796; called by muse, mutect2
- TIGIT | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs201068475; called by muse, varscan2
- TMPRSS11A | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs187902089; called by muse, mutect2
- TTLL8 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs759605055, COSV99838438; called by muse, mutect2
- XDH | c.3107G>A p.G1036E | Missense Mutation (SNP) | VAF 51/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65151270; called by muse, mutect2
- ARCN1 | c.754T>A p.S252T | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- BRINP3 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.785); called by muse, mutect2
- C12orf42 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- DNAH17 | c.9731G>A p.W3244* | Nonsense Mutation (SNP) | VAF 68/506 reads (13%) | called by muse, mutect2, varscan2
- FBN1 | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.167); called by muse, mutect2
- FMN2 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C2 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 45/472 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- MSL1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFV1 | c.914-8G>A | Splice Region (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2
- OR5B17 | c.584T>A p.L195* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- PDCD1LG2 | c.802dup p.E268Gfs*16 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- PIP5K1C | c.1772A>G p.K591R | Missense Mutation (SNP) | VAF 28/485 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- RYR2 | c.5788G>T p.D1930Y | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- TBC1D10C | c.426A>C p.Q142H | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCERG1 | c.3000dup p.Q1001Tfs*5 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- TP53 | c.98_123del p.S33* | Frame Shift Del (DEL) | VAF 18/208 reads (9%) | called by mutect2, pindel
- UNC80 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- ZNF679 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ADA2 | c.1287G>A p.L429= (on ENST00000262607; = p.L188= on NM_177405.3) | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- CDH4 | c.480C>T p.N160= | Silent (SNP) | VAF 38/265 reads (14%) | catalogued as rs149210026; called by muse, mutect2, varscan2
- CRYBB1 | c.531C>T p.Y177= | Silent (SNP) | VAF 48/669 reads (7%) | catalogued as rs141329615; called by muse, mutect2
- ELOVL1 | c.528C>T p.V176= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- GALC | c.1572C>T p.G524= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs753164684, COSV54327217; called by muse, mutect2, varscan2
- KIF5C | c.2721C>T p.A907= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs913003939, COSV68483950; called by muse, mutect2
- NEFL | c.528G>A p.A176= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs760320750; called by muse, mutect2
- NPFFR2 | c.1203C>T p.Y401= | Silent (SNP) | VAF 25/378 reads (7%) | catalogued as rs538543232, COSV100440247, COSV58146856, COSV58152388; called by muse, mutect2
- PKD1 | c.843C>T p.H281= | Silent (SNP) | VAF 38/586 reads (6%) | catalogued as rs760237424, COSV99238465; called by muse, mutect2
- PXDNL | c.3264G>A p.P1088= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV62486212; called by muse, mutect2
- SLC26A9 | c.1998C>T p.I666= | Silent (SNP) | VAF 25/267 reads (9%) | called by muse, mutect2
- SREBF1 | c.588C>T p.V196= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs771640474; called by muse, mutect2
- TLDC2 | c.625C>T p.L209= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- USP35 | c.1539C>T p.F513= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs779861899; called by muse, mutect2, varscan2
- AFDN | chr6:167976465 G>A | 3'Flank (SNP) | VAF 5/13 reads (38%) | catalogued as rs4708420; called by muse, varscan2
- DCHS2 | n.4111C>T | RNA (SNP) | VAF 5/50 reads (10%) | catalogued as COSV61781968; called by muse, mutect2, varscan2
- FAM90A27P | n.599C>T | RNA (SNP) | VAF 17/100 reads (17%) | catalogued as rs1010631516; called by muse, mutect2, varscan2
- MORF4 | n.448T>C | RNA (SNP) | VAF 26/297 reads (9%) | called by muse, mutect2
- TMEM183B | n.844G>A | RNA (SNP) | VAF 40/440 reads (9%) | catalogued as rs776679628; called by muse, mutect2
